Somatic mutation profile of tumor specimen TCGA-D5-6898-01A (aliquot TCGA-D5-6898-01A-11D-1924-10) from TCGA case TCGA-D5-6898, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.7 years (18,874 days).
Specimen TCGA-D5-6898-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df1b739-d350-48db-a11f-61966607699a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6898-10A (Blood Derived Normal), aliquot TCGA-D5-6898-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3ff2454-5937-43de-a0e8-eec8818ad157

The open-access MAF lists 87 somatic variants for this specimen: 64 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Nonsense Mutation 5, Frame Shift Ins 4, Splice Site 2, Intron 2, In Frame Ins 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs74821926, CM870084, CM890279, CM910022, COSV55735814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 39/55 reads (71%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 79/123 reads (64%) | catalogued as rs780619951, CM960099, COSV53736642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 65/102 reads (64%) | hotspot (GDC flag); catalogued as rs1362274408, COSV55920408; called by muse, mutect2, varscan2
- ADAMTS1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV53168674; called by muse, mutect2, varscan2
- ADAMTS3 | c.1141A>T p.S381C | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99710215; called by muse, mutect2, varscan2
- ATP2B2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs766306375, COSV59488988; called by muse, mutect2, varscan2
- CALN1 | c.659A>G p.*220Wext*44 (on ENST00000329008 / NM_001017440.3; = p.*262Wext*44 on NM_031468.4) | Nonstop Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61119738; called by muse, mutect2, varscan2
- CAMTA1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1405074736, COSV57881973; called by muse, mutect2, varscan2
- CCDC88C | c.4674T>A p.F1558L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57795837; called by muse, mutect2, varscan2
- CDC42BPB | c.3505C>A p.R1169S | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV100775401, COSV63473862; called by muse, mutect2, varscan2
- COL27A1 | c.3610G>A p.G1204R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282029048, COSV61921496; called by muse, mutect2, varscan2
- CUL1 | c.1742G>T p.W581L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296427; called by muse, mutect2, varscan2
- DCAF11 | c.780-1G>T p.X260_splice | Splice Site (SNP) | VAF 8/114 reads (7%) | catalogued as COSV58108215; called by muse, mutect2
- DCAF4L2 | c.780C>G p.S260R | Missense Mutation (SNP) | VAF 89/144 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60476418; called by muse, mutect2, varscan2
- DDX60 | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV101190242; called by muse, mutect2, varscan2
- DEFB121 | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 61/485 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV66235992; called by muse, mutect2, varscan2
- DNAH11 | c.10471C>T p.R3491C | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162504533, COSV60937534; called by muse, mutect2, varscan2
- ESF1 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 114/170 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52518895; called by muse, mutect2, varscan2
- ETFBKMT | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100740338; called by muse, mutect2, varscan2
- FAM47C | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63728177; called by muse, mutect2, varscan2
- FANCI | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55522747; called by muse, mutect2, varscan2
- FCN2 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs147569918; called by muse, mutect2, varscan2
- FZD10 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs1566096577, COSV57472117; called by muse, mutect2, varscan2
- GABRA3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV64795195; called by muse, mutect2, varscan2
- GOLGB1 | c.8778T>A p.D2926E | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100510336; called by muse, mutect2, varscan2
- GTF3C2 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53124993; called by muse, mutect2, varscan2
- INTS1 | c.5944G>A p.A1982T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs749474268, COSV101247432; called by muse, varscan2
- LGALS14 | c.113T>G p.V38G | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100648402; called by muse, mutect2, varscan2
- LRRK2 | c.1832G>C p.G611A | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV54143858; called by muse, mutect2, varscan2
- MAGEC1 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as COSV53567861; called by muse, mutect2, varscan2
- MUC16 | c.42177C>A p.F14059L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.825); catalogued as COSV66689817, COSV66689989; called by muse, mutect2, varscan2
- MUC16 | c.33908C>A p.S11303Y | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.534); catalogued as COSV67444598; called by muse, mutect2, varscan2
- NDUFS1 | c.1553+1G>T p.X518_splice | Splice Site (SNP) | VAF 19/97 reads (20%) | catalogued as COSV51907925; called by muse, mutect2, varscan2
- NFE2L3 | c.1022C>A p.P341Q | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs779702861, COSV50226287; called by muse, mutect2, varscan2
- NHEJ1 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV59427483; called by muse, mutect2, varscan2
- NLRP12 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs1383087110, COSV100145246, COSV60743523; called by muse, mutect2, varscan2
- OPLAH | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs371821782; called by muse, mutect2, varscan2
- OR10K1 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 101/165 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV56870542; called by muse, mutect2, varscan2
- OSBPL5 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV55139382; called by muse, mutect2, varscan2
- PCBP3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.164); catalogued as rs191946294, COSV68406544; called by mutect2, varscan2
- PCDH9 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV60528623; called by muse, mutect2, varscan2
- PCDHA7 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs570116646, COSV65341809; called by muse, mutect2, varscan2
- PCDHAC1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1179807732, COSV53836554; called by muse, mutect2, varscan2
- PCDHAC1 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1554206828, COSV53836704; called by muse, mutect2, varscan2
- PDE1C | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs772885431, COSV68811290; called by mutect2, varscan2
- PIGO | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53052421; called by muse, mutect2, varscan2
- PKDREJ | c.4107C>A p.N1369K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV53546432; called by muse, mutect2, varscan2
- SAMD9 | c.676T>A p.C226S | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66072985; called by muse, mutect2, varscan2
- SLC45A4 | c.1358G>A p.R453H (on ENST00000517878 / NM_001286646.2; = p.R402H on NM_001080431.2) | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs748393317, COSV50132972; called by muse, mutect2, varscan2
- SPECC1L | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV58656405; called by muse, mutect2, varscan2
- STXBP5 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs551518103, COSV51647840; called by muse, mutect2, varscan2
- TAF5 | c.2289G>T p.E763D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58915254; called by muse, mutect2, varscan2
- TBC1D32 | c.1415T>G p.L472R | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51536221; called by muse, mutect2, varscan2
- TLR4 | c.1661A>G p.N554S (on ENST00000355622 / NM_138554.5; = p.N514S on NM_003266.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62922423; called by muse, mutect2, varscan2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, mutect2, varscan2
- TTBK1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs761667946, COSV52488080; called by muse, mutect2, varscan2
- ZDBF2 | c.4367G>T p.C1456F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65621898; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1289dup p.N430Kfs*13 | Frame Shift Ins (INS) | VAF 14/55 reads (25%) | called by mutect2, varscan2
- ERCC1 | c.62_68dup p.P25Cfs*8 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, varscan2
- POLM | c.214_219dup p.E72_E73dup | In Frame Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- SLC12A2 | c.3354dup p.E1119Rfs*7 | Frame Shift Ins (INS) | VAF 95/245 reads (39%) | called by mutect2, pindel, varscan2
- WDR35 | c.2343dup p.R782* (on ENST00000345530 / NM_001006657.2; = p.R771* on NM_020779.4) | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- ZNF683 | c.1366G>A p.V456M (on ENST00000403843; = p.V436M on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2
- BTD | c.1260G>C p.L420= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV57728455; called by muse, mutect2, varscan2
- CAMSAP2 | c.3165G>A p.L1055= (on ENST00000236925 / NM_001297707.2; = p.L1044= on NM_203459.3) | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV52666826; called by muse, mutect2, varscan2
- CCDC170 | c.651T>C p.T217= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV53336586; called by muse, mutect2, varscan2
- CCKBR | c.882C>T p.Y294= | Silent (SNP) | VAF 112/295 reads (38%) | catalogued as rs766130597, COSV58098624, COSV58107170; called by muse, mutect2, varscan2
- CNR1 | c.1287G>A p.S429= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs149238893; called by muse, mutect2, varscan2
- DR1 | c.249C>T p.Y83= | Silent (SNP) | VAF 64/346 reads (18%) | catalogued as COSV64725273; called by muse, mutect2, varscan2
- GPC6 | c.1428C>T p.N476= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs146868653; called by muse, mutect2, varscan2
- KRT83 | c.1389C>T p.N463= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs1049248799, COSV53338360; called by muse, mutect2, varscan2
- LRRC52 | c.771C>T p.A257= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs761775233, COSV54231247; called by muse, mutect2, varscan2
- LTK | c.1002C>T p.G334= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs542040990, COSV55489027; called by muse, mutect2, varscan2
- MAN1B1 | c.297C>G p.L99= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV64306144; called by muse, mutect2, varscan2
- MYH7B | c.402G>A p.T134= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1232234978, COSV53416526; called by muse, mutect2, varscan2
- NLRP2 | c.1830C>T p.Y610= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as rs551890882, COSV54752353; called by muse, mutect2, varscan2
- NUFIP2 | c.999G>A p.S333= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs748179678, COSV56602144; called by muse, mutect2, varscan2
- POU4F3 | c.555C>T p.R185= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV57942313; called by muse, mutect2, varscan2
- PTPRE | c.810C>T p.V270= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs992013855, COSV54546314; called by muse, mutect2, varscan2
- SLC6A19 | c.1599G>A p.T533= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as rs112479136, COSV57249545; called by muse, mutect2, varscan2
- STAB1 | c.2397G>T p.G799= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1446102475, COSV58732087; called by muse, mutect2, varscan2
- TRPC5 | c.1737A>T p.V579= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV53284029; called by muse, mutect2, varscan2
- ZNF584 | c.42G>A p.Q14= | Silent (SNP) | VAF 22/212 reads (10%) | catalogued as COSV59721838; called by muse, mutect2, varscan2
- ABLIM2 | c.1516+2732G>A | Intron (SNP) | VAF 13/26 reads (50%) | catalogued as rs761369594, COSV99588978; called by muse, mutect2, varscan2
- AC074085.2 | n.64C>T | RNA (SNP) | VAF 12/22 reads (55%) | catalogued as rs1437384450; called by muse, mutect2, varscan2
- PHACTR1 | c.664+2205C>A | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100275489; called by mutect2, varscan2
